Surgical pathology report (de-identified scan), TCGA case TCGA-NA-A5I1, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Duke University, specimen TCGA-NA-A5I1-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinosarcoma / mixed
Mullerian Tumor 8980/3

Site: Uterus, NOS

C55.9

1/10/13 GW

Surg Path

CLINICAL HISTORY:

Malignant neoplasm corpus uteri.

GROSS EXAMINATION:

A. "Uterus and bilateral adnexa", received in formalin is a 600 gm. 14 x 11 x 7.5 cm. specimen consisting of uterus and bilateral fallopian tubes and ovaries. Opening of the uterus discloses that approximately 90% of the endometrial cavity is replaced by numerous exophytic, fleshy, partially necrotic tumor masses (largest mass 6.5 cm). The tumor masses involve both the anterior and posterior walls as well as the anterior and posterior lower uterine segments. The cervix is grossly free of tumor both in both anterior and posterior aspects. The tumor grossly extends to within 1 mm of the serosal surface in the posterior fundus, but the serosal surface is grossly free of tumor. Both the right and left ovaries and fallopian tubes are grossly unremarkable and free of tumor.

BLOCK SUMMARY:

- A1- anterior cervix
- A2- posterior cervix
- A3- anterior lower uterine segment of tumor
- A4- posterior lower uterine segment of tumor
- A5-6- full thickness section anterior endomyometrium with tumor
- A7-8- posterior endomyometrium full thickness section with tumor
- A9-10- additional sections of tumor
- A11- left ovary and fallopian tube
- A12- right ovary and fallopian tube

B. "Posterior upper vagina", received in formalin is a 2.8 x 1 x 0.9 cm fragment of white, soft tissue with a mucosal surface. The soft tissue margin is inked blue. The specimen is sectioned and submitted entirely in B1-2.

C. "Posterior vaginal margins", received in formalin is a 2.5 x 1.2 x 1 cm segment of white, soft tissue with a mucosal surface. The soft tissue margin is inked blue. The specimen is sectioned and submitted entirely in C1-3.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTEROSALPINGO-OOPHORECTOMY

PATHOLOGIC STAGE (AJCC 6th Edition): pT3 pNx pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "UTERUS AND BILATERAL ADNEXA":

[page 2 of 2]
UTERUS: 600 GRAMS

ENDOMETRIUM:

TUMOR SITE: DIFFUSE

HISTOLOGIC TYPE: CARCINOSARCOMA.

FIGO GRADE: 3

TUMOR SIZE: APPROXIMATELY 10 X 8 X 2 CM.

MAXIMUM DEPTH OF MYOMETRIAL INVASION: 0.0 CM, IN A 1.0 CM THICK WALL.

LYMPHATIC/VASCULAR INVASION: PRESENT

ADJACENT NON-NEOPLASTIC ENDOMETRIUM: ATROPHIC

REMAINING MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS

CERVIX: NEGATIVE FOR TUMOR (NO SQUAMOUS EPITHELIUM IS IDENTIFIED)

SEE COMMENT.

SEROSA: NEGATIVE FOR TUMOR.

RIGHT AND LEFT OVARIES: NEGATIVE FOR TUMOR.

RIGHT AND LEFT FALLOPIAN TUBES: NEGATIVE FOR TUMOR.

B. "POSTERIOR UPPER VAGINA":

MALIGNANT SURFACE GLANDS CONSISTENT WITH CARCINOMATOUS COMPONENT OF
CARCINOSARCOMA, SEE COMMENT.

C. "POSTERIOR VAGINA MARGINS":

NEGATIVE FOR MALIGNANCY.

COMMENT: The endometrial lesion is a carcinosarcoma with heterologous elements (malignant mixed müllerian tumor). The tumor has a well circumscribed, broad junction with the myometrium, but no definite myometrial invasion is seen. However, tumor is present, at point of closest approach, 4 mm from the serosal surface of the uterus. has reviewed portions of this case. Part B is not oriented, so it is possible that the actual margin is negative, but clinical correlation is needed.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file aa3306ed-c15f-43d9-a451-640f65441338 (TCGA-NA-A5I1.1D93ACE7-15D8-4502-AE9B-BF9AB63E95F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).